Somatic mutation profile of tumor specimen 0DNWLN from CCDI case PBCBXF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 16.2 years (5,914 days).
Specimen 0DNWLN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a006d7f-1f20-4a49-a7cf-4ff973d82512.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cef430f-f367-4d06-aca3-fa2cdefdfb1f

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2W1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs531323748; called by muse, mutect2, varscan2
- DEPTOR | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs758875987; called by muse, mutect2, varscan2
- LPAR3 | c.40dup p.Y14Lfs*2 | Frame Shift Ins (INS) | VAF 111/376 reads (30%) | catalogued as rs767032705; called by mutect2, varscan2
- SMC5 | c.2630C>A p.S877* | Nonsense Mutation (SNP) | VAF 104/793 reads (13%) | catalogued as COSV63194597; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 26/829 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- EFHC2 | c.1369T>C p.Y457H | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SMC1B | c.3159A>C p.Q1053H | Missense Mutation (SNP) | VAF 169/661 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- XPO7 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 73/583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 36/243 reads (15%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99987084; called by muse, varscan2
- MRPL21 | c.232+83C>A | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- STX2 | c.-13C>T | 5'UTR (SNP) | VAF 14/251 reads (6%) | catalogued as rs1404443810; called by muse, mutect2
